Somatic mutation profile of tumor specimen TCGA-2G-AAF1-01A (aliquot TCGA-2G-AAF1-01A-11D-A42Y-10) from TCGA case TCGA-2G-AAF1, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 28.8 years (10,511 days).
Specimen TCGA-2G-AAF1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c68913e6-27b2-4f46-86ad-5c92f9cea96d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAF1-10A (Blood Derived Normal), aliquot TCGA-2G-AAF1-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/26a22ddd-6f87-49f3-883e-d9ef63c87270

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.2446G>T p.D816Y | Missense Mutation (SNP) | VAF 10/77 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs121913506, COSV55386862, COSV55387240, COSV55408330; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RAP1B | c.331A>G p.M111V | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.522); catalogued as rs372360254; called by muse, mutect2
- KIF5B | c.1052A>G p.N351S | Missense Mutation (SNP) | VAF 11/158 reads (7%) | SIFT tolerated (0.77); PolyPhen benign (0.001); called by muse, mutect2
- RAI14 | c.1565T>C p.F522S | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- VDAC2 | c.22T>A p.C8S | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated, low confidence (0.53); PolyPhen possibly damaging (0.478); called by muse, varscan2
- IFT46 | c.774C>T p.S258= (on ENST00000264021 / NM_001168618.2; = p.S309= on NM_020153.3) | Silent (SNP) | VAF 9/88 reads (10%) | catalogued as rs782417140; called by muse, mutect2, varscan2
- TKT | c.1035C>G p.S345= | Silent (SNP) | VAF 10/150 reads (7%) | called by muse, mutect2
